Somatic mutation profile of tumor specimen MP2PRT-PAUNIT-TMP1-A (aliquot MP2PRT-PAUNIT-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PAUNIT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 7.0 years (2,563 days).
Specimen MP2PRT-PAUNIT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41eea381-c651-40c6-8f88-087bb150951d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUNIT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUNIT-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e5ba73c-3b78-46ff-a841-594db5611cbf

The open-access MAF lists 87 somatic variants for this specimen: 56 protein-altering or splice-affecting, 28 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 28, Nonsense Mutation 4, Intron 2, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 57/238 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 26/275 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ALX4 | c.901G>A p.A301T | Missense Mutation (SNP) | VAF 49/184 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.177); catalogued as rs766411205, COSV100241337, COSV61326754; called by muse, mutect2, varscan2
- CLIC6 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 124/1129 reads (11%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.679); catalogued as rs1426965617; called by muse, mutect2, varscan2
- CNOT4 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 58/321 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV59655715; called by muse, mutect2, varscan2
- DSP | c.6689C>T p.P2230L | Missense Mutation (SNP) | VAF 46/238 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs759982048; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EDA2R | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 67/730 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.025); catalogued as rs1277379025; called by muse, mutect2
- FASN | c.1955C>T p.S652L | Missense Mutation (SNP) | VAF 94/564 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1199734379; called by muse, mutect2, varscan2
- FBN2 | c.3793G>A p.E1265K | Missense Mutation (SNP) | VAF 62/251 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as rs776031352, CM158361, COSV52514792; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPRASP2 | c.1891C>T p.R631* | Nonsense Mutation (SNP) | VAF 42/587 reads (7%) | catalogued as rs748760002; called by muse, mutect2
- IMPG1 | c.535C>A p.P179T | Missense Mutation (SNP) | VAF 15/304 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV64062069; called by muse, mutect2
- KLK11 | c.418C>T p.R140C (on ENST00000594768 / NM_144947.3; = p.R108C on NM_006853.3) | Missense Mutation (SNP) | VAF 82/361 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as rs757800111; called by muse, mutect2, varscan2
- LMTK2 | c.3202C>T p.P1068S | Missense Mutation (SNP) | VAF 93/394 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.049); catalogued as rs1210091003; called by mutect2, varscan2
- LPGAT1 | c.1001C>T p.S334F | Missense Mutation (SNP) | VAF 59/404 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as rs763468305; called by muse, mutect2, varscan2
- LSS | c.1223C>T p.S408L | Missense Mutation (SNP) | VAF 86/742 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs769927478, COSV62700352; called by muse, mutect2, varscan2
- MAMDC4 | c.2817G>A p.W939* (on ENST00000445819; = p.W860* on NM_206920.3) | Nonsense Mutation (SNP) | VAF 50/308 reads (16%) | catalogued as rs1271858916; called by muse, mutect2, varscan2
- MYPN | c.14G>A p.S5N | Missense Mutation (SNP) | VAF 74/277 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV100589559; called by muse, mutect2, varscan2
- OR2B3 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 96/662 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV65850969; called by muse, mutect2, varscan2
- PAPOLB | c.284G>A p.G95E | Missense Mutation (SNP) | VAF 51/297 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68202814; called by muse, mutect2, varscan2
- PEX5L | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 57/254 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs759355045, COSV55855547; called by muse, mutect2, varscan2
- PPP1R26 | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 69/377 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.141); catalogued as rs369152269, COSV63354543; called by muse, mutect2, varscan2
- PTPRT | c.2756G>A p.G919E | Missense Mutation (SNP) | VAF 33/188 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.331); catalogued as COSV61978084; called by muse, mutect2, varscan2
- SAMD9 | c.2576C>T p.P859L | Missense Mutation (SNP) | VAF 35/203 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs1395482864; called by muse, mutect2, varscan2
- SFRP5 | c.841G>A p.V281I | Missense Mutation (SNP) | VAF 80/517 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs540580661, COSV56604627; called by muse, mutect2, varscan2
- WLS | c.1150G>A p.V384M | Missense Mutation (SNP) | VAF 28/222 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.692); catalogued as rs541018004; called by muse, mutect2, varscan2
- WWC3 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 79/793 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.754); catalogued as COSV66506630; called by muse, mutect2, varscan2
- ZNF492 | c.1562C>T p.S521F | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.298); catalogued as COSV101513986; called by muse, mutect2, varscan2
- ZNF532 | c.3826G>A p.E1276K | Missense Mutation (SNP) | VAF 43/295 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1384480176; called by muse, mutect2, varscan2
- ZNF891 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 59/277 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs765139625, COSV68332860; called by muse, mutect2, varscan2
- ABLIM1 | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 42/312 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AFAP1 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 57/461 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- AL772284.1 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 127/1058 reads (12%) | SIFT tolerated (0.32); called by muse, mutect2, varscan2
- ARF3 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 50/234 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- C12orf66 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 78/362 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- EPB41L3 | c.1778C>T p.P593L | Missense Mutation (SNP) | VAF 60/516 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.141); called by muse, varscan2
- EPGN | c.58A>G p.T20A | Missense Mutation (SNP) | VAF 57/385 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM83A | c.922G>A p.V308I | Missense Mutation (SNP) | VAF 106/454 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, varscan2
- GDA | c.81G>T p.E27D | Missense Mutation (SNP) | VAF 41/333 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ITPR2 | c.3678+1G>A p.X1226_splice | Splice Site (SNP) | VAF 33/174 reads (19%) | called by muse, mutect2, varscan2
- KCNH8 | c.2990A>C p.H997P | Missense Mutation (SNP) | VAF 79/343 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LMTK2 | c.3203C>T p.P1068L | Missense Mutation (SNP) | VAF 102/429 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- MAMDC4 | c.2816G>A p.W939* (on ENST00000445819; = p.W860* on NM_206920.3) | Nonsense Mutation (SNP) | VAF 52/313 reads (17%) | called by muse, mutect2, varscan2
- MUC5B | c.17197G>A p.D5733N | Missense Mutation (SNP) | VAF 113/439 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- NLGN2 | c.28G>A p.G10R | Missense Mutation (SNP) | VAF 141/396 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRP1 | c.1783C>T p.P595S | Missense Mutation (SNP) | VAF 81/348 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RASGRF1 | c.860G>T p.S287I | Missense Mutation (SNP) | VAF 52/217 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- RNF212 | c.379C>G p.Q127E | Missense Mutation (SNP) | VAF 27/281 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.104); called by muse, mutect2
- ROR1 | c.2716T>A p.S906T | Missense Mutation (SNP) | VAF 44/237 reads (19%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- SAMD9 | c.2575C>T p.P859S | Missense Mutation (SNP) | VAF 36/206 reads (17%) | SIFT tolerated (0.82); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SDK1 | c.2524G>A p.E842K | Missense Mutation (SNP) | VAF 72/340 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- SLC25A12 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 42/213 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- SNAP91 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 58/376 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPNS3 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 100/640 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRRAP | c.11189G>A p.R3730Q (on ENST00000359863 / NM_001244580.1; = p.R3701Q on NM_003496.3) | Missense Mutation (SNP) | VAF 32/435 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- WNK3 | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 46/458 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF816-ZNF321P | c.271C>T p.Q91* | Nonsense Mutation (SNP) | VAF 37/226 reads (16%) | called by muse, mutect2, varscan2
- ABCD1 | c.1110G>A p.L370= | Silent (SNP) | VAF 50/517 reads (10%) | catalogued as COSV99497545; called by muse, mutect2, varscan2
- ARF3 | c.441C>T p.S147= | Silent (SNP) | VAF 50/238 reads (21%) | catalogued as rs751619589, COSV99873007; called by muse, mutect2, varscan2
- ARHGEF11 | c.43C>T p.L15= | Silent (SNP) | VAF 36/267 reads (13%) | called by muse, mutect2, varscan2
- C8orf48 | c.813C>T p.I271= | Silent (SNP) | VAF 51/256 reads (20%) | called by muse, mutect2, varscan2
- CFAP47 | c.6345G>A p.A2115= | Silent (SNP) | VAF 50/443 reads (11%) | catalogued as rs1290982428, COSV59152179; called by muse, mutect2, varscan2
- DSC2 | c.429G>A p.S143= | Silent (SNP) | VAF 52/425 reads (12%) | catalogued as rs542638302, COSV51865824; called by muse, mutect2, varscan2
- ESRRB | c.1164G>A p.R388= | Silent (SNP) | VAF 78/436 reads (18%) | catalogued as rs777803891; called by muse, mutect2, varscan2
- FAT4 | c.6663G>A p.K2221= | Silent (SNP) | VAF 74/463 reads (16%) | catalogued as COSV100628949; called by muse, mutect2, varscan2
- FHOD3 | c.2922G>A p.T974= (on ENST00000359247 / NM_001281739.3; = p.T991= on NM_025135.5) | Silent (SNP) | VAF 53/431 reads (12%) | catalogued as rs376964118; called by muse, mutect2, varscan2
- GGACT | c.96G>A p.A32= | Silent (SNP) | VAF 52/458 reads (11%) | catalogued as rs1393009287; called by muse, mutect2, varscan2
- HRNR | c.6495C>T p.G2165= | Silent (SNP) | VAF 140/4332 reads (3%) | catalogued as rs1163324143; called by muse, mutect2
- KLF16 | c.747C>T p.P249= | Silent (SNP) | VAF 35/338 reads (10%) | catalogued as rs560954438; called by muse, mutect2, varscan2
- KRTAP24-1 | c.441C>T p.N147= | Silent (SNP) | VAF 48/707 reads (7%) | catalogued as rs146940107; called by muse, mutect2
- LRP2 | c.1704G>A p.S568= | Silent (SNP) | VAF 64/374 reads (17%) | catalogued as rs774520988, COSV99786970; called by muse, mutect2, varscan2
- MTTP | c.2628G>A p.E876= | Silent (SNP) | VAF 78/491 reads (16%) | called by muse, mutect2, varscan2
- MYO7B | c.4515C>T p.F1505= | Silent (SNP) | VAF 31/172 reads (18%) | catalogued as rs754713878; called by muse, mutect2, varscan2
- PNKP | c.885C>T p.A295= | Silent (SNP) | VAF 109/500 reads (22%) | catalogued as rs763725051; ClinVar: likely benign; called by muse, mutect2, varscan2
- PPP1R3C | c.702C>T p.F234= | Silent (SNP) | VAF 60/452 reads (13%) | called by muse, mutect2, varscan2
- RAP1GAP | c.1602G>A p.S534= | Silent (SNP) | VAF 62/283 reads (22%) | catalogued as rs376717211; called by muse, mutect2, varscan2
- SCNN1G | c.1170G>A p.S390= | Silent (SNP) | VAF 79/332 reads (24%) | catalogued as rs767064525; called by muse, mutect2, varscan2
- SYNM | c.2895G>A p.R965= | Silent (SNP) | VAF 95/321 reads (30%) | called by muse, mutect2, varscan2
- TMEM132B | c.1341C>T p.V447= | Silent (SNP) | VAF 65/332 reads (20%) | catalogued as rs773751171, COSV54747870; called by muse, mutect2, varscan2
- TNXB | c.9121C>T p.L3041= (on ENST00000647633; = p.L2794= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 108/766 reads (14%) | called by muse, mutect2, varscan2
- TRMT44 | c.384C>T p.G128= | Silent (SNP) | VAF 20/802 reads (2%) | called by muse, mutect2
- TUT4 | c.2242C>T p.L748= | Silent (SNP) | VAF 65/378 reads (17%) | called by muse, mutect2, varscan2
- USH2A | c.5361G>A p.V1787= | Silent (SNP) | VAF 112/404 reads (28%) | catalogued as COSV56389213; called by muse, mutect2, varscan2
- ZNF462 | c.2154C>T p.I718= | Silent (SNP) | VAF 79/297 reads (27%) | called by muse, mutect2, varscan2
- ZNF630 | c.1488C>T p.F496= | Silent (SNP) | VAF 84/830 reads (10%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+10640C>T | Intron (SNP) | VAF 51/246 reads (21%) | called by muse, mutect2, varscan2
- NRXN1 | c.3719-1446G>A | Intron (SNP) | VAF 39/174 reads (22%) | catalogued as COSV100639601; called by muse, mutect2, varscan2
- OXSR1 | c.*1395C>T | 3'UTR (SNP) | VAF 39/191 reads (20%) | catalogued as rs1478934278; called by muse, mutect2, varscan2
